Somatic mutation profile of tumor specimen TARGET-10-PAREPB-09A (aliquot TARGET-10-PAREPB-09A-01D) from TARGET case TARGET-10-PAREPB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,254 days).
Specimen TARGET-10-PAREPB-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5c82f42-e222-4806-a03b-0e2ae4542293.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAREPB-10A (Blood Derived Normal), aliquot TARGET-10-PAREPB-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8efd75b8-6e76-4569-aa83-e5ff0dafcb37

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, 3'UTR 2, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 15/83 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASB4 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as rs762395018, COSV57507880; called by muse, mutect2, varscan2
- CDH11 | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as rs770554222; called by muse, mutect2, varscan2
- CHPT1 | c.420A>G p.T140= | Splice Region (SNP) | VAF 24/120 reads (20%) | catalogued as rs1020181240, COSV99037705; called by muse, mutect2, varscan2
- CLINT1 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs746859496, COSV51626145; called by muse, mutect2, varscan2
- CNKSR2 | c.988G>A p.V330I | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs759498814, COSV54249894; ClinVar: benign; called by muse, mutect2, varscan2
- FAT2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201874812, COSV55828205; called by muse, mutect2, varscan2
- KDM4E | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.84); catalogued as rs374081859; called by muse, mutect2, varscan2
- MYO7B | c.4636G>A p.G1546S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs757343752, COSV67350115; called by muse, mutect2, varscan2
- NAALADL2 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs745780062; called by muse, mutect2, varscan2
- THBS1 | c.3332G>A p.R1111H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370392120; called by muse, mutect2, varscan2
- VARS1 | c.2314G>A p.G772R | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs369603016; called by muse, mutect2, varscan2
- ETV6 | c.601dup p.L201Pfs*16 | Frame Shift Ins (INS) | VAF 29/168 reads (17%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.1272A>T p.K424N | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRKG1 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HTR3E | c.1051C>T p.L351= (on ENST00000415389 / NM_001256613.1; = p.L366= on NM_182589.2) | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- TMEM79 | c.261G>A p.P87= | Silent (SNP) | VAF 32/150 reads (21%) | catalogued as rs543664557, COSV55296768; called by muse, mutect2, varscan2
- DMTN | c.*562C>A | 3'UTR (SNP) | VAF 22/181 reads (12%) | catalogued as rs200296992; called by muse, mutect2, varscan2
- SMIM20 | c.*64T>C | 3'UTR (SNP) | VAF 26/118 reads (22%) | catalogued as rs1215673621; called by muse, mutect2, varscan2
